Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-AB20, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-AB20-01A (Primary Tumor).

[page 1 of 5]
ICD O-3

Adenocarcinoma NOS 8140/3

Site: Prostate NOS C61.9

4/25/14

Accession Date:

Collection Date:

FINAL DIAGNOSIS:

PART 1: LYMPH NODE, RIGHT PELVIC, EXCISION—

TEN BENIGN LYMPH NODES, NEGATIVE FOR CARCINOMA (0/10).

PART 2: LYMPH NODE, LEFT PELVIC, EXCISION—

EIGHT BENIGN LYMPH NODES, NEGATIVE FOR CARCINOMA (0/8). PENDING RECUT ON 2B.

PART 3: ANTERIOR FAT PAD, RESECTION—

MATURE ADIPOSE TISSUE, NEGATIVE FOR CARCINOMA.

PART 4: PROSTATE, BILATERAL SEMINAL VESICLES AND DISTAL VASA DEFERENTIA, RADICAL PROSTATECTOMY —

A. INVASIVE MODERATELY DIFFERENTIATED ADENOCARCINOMA, ACINAR TYPE, GLEASON SCORE 3 + 3 = 6,

WITH TERTIARY GLEASON PATTERN 4.

B. CARCINOMA INVOLVES BOTH RIGHT AND LEFT LOBES WITH A GREATEST NODULAR DIAMETER OF 1.0 cm.

C. CARCINOMA INVOLVES LESS THAN 5% OF THE EXAMINED PROSTATE VOLUME.

D. NO EXTRACAPSULAR EXTENSION OF CARCINOMA IS IDENTIFIED.

E. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.

F. ALL SURGICAL MARGINS OF RESECTION ARE FREE OF CARCINOMA; CLOSEST MARGIN IS LESS THAN 0.1

CM IN THE REGION OF THE RIGHT POSTERIOR APEX (Slide 4AA).

G. PERINEURAL INVASION IS IDENTIFIED.

H. LYMPHOVASCULAR INVASION IS NOT IDENTIFIED.

I. MULTIFOCAL HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.

J. PATHOLOGIC TNM STAGE (AJCC 7th EDITION) pT2c, N0 MX.

K. TNM HISTOLOGIC GRADE: G2.

L. NON-NEOPLASTIC PROSTATE WITH BENIGN PROSTATIC HYPERPLASIA.

PART 5: SPERMATIC CORD, LIPOMA, RESECTION—
FRAGMENTS OF LIPOMA, 6.5 CM.

[page 2 of 5]
Anonymous No.: _____

Age: 62

Gender: M

Race: Patient Decline

CLINICAL HISTORY

The patient is a 62-year-old male with a history of PSA value of 3.8. The patient also has a history of biopsy on [REDACTED], this biopsy reveals: moderately differentiated prostatic adenocarcinoma Gleason score 3+3=6 in the right apex and poorly differentiated prostatic adenocarcinoma Gleason score 4+3=7 in the left apex.

PRE-OP DIAGNOSIS: prostate cancer

POST-OP DIAGNOSIS: same

PROCEDURE: prostatectomy.

FINAL DIAGNOSIS

PART 1: LYMPH NODE, RIGHT PELVIC, EXCISION

TEN BENIGN LYMPH NODES, NEGATIVE FOR CARCINOMA (0/10).

PART 2: LYMPH NODE, LEFT PELVIC, EXCISION

EIGHT BENIGN LYMPH NODES, NEGATIVE FOR CARCINOMA (0/8). PENDING RECUT ON 2B.

PART 3: ANTERIOR FAT PAD, RESECTION

MATURE ADIPOSE TISSUE, NEGATIVE FOR CARCINOMA.

PART 4: PROSTATE, BILATERAL SEMINAL VESICLES AND DISTAL VASA DEFERENTIA, RADICAL PROSTATECTOMY

- A. INVASIVE MODERATELY DIFFERENTIATED ADENOCARCINOMA, ACINAR TYPE, GLEASON SCORE 3 + 3 = 6, WITH TERTIARY GLEASON PATTERN 4.
- B. CARCINOMA INVOLVES BOTH RIGHT AND LEFT LOBES WITH A GREATEST NODULAR DIAMETER OF 1.0 cm.
- C. CARCINOMA INVOLVES LESS THAN 5% OF THE EXAMINED PROSTATE VOLUME.
- D. NO EXTRACAPSULAR EXTENSION OF CARCINOMA IS IDENTIFIED.
- E. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- F. ALL SURGICAL MARGINS OF RESECTION ARE FREE OF CARCINOMA; CLOSEST MARGIN IS LESS THAN 0.1 CM IN THE REGION OF THE RIGHT POSTERIOR APEX (Slide 4AA).
- G. PERINEURAL INVASION IS IDENTIFIED.
- H. LYMPHOVASCULAR INVASION IS NOT IDENTIFIED.
- I. MULTIFOCAL HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- J. PATHOLOGIC TNM STAGE (AJCC 7th EDITION) pT2c, N0 MX.
- K. TNM HISTOLOGIC GRADE: G2.
- L. NON-NEOPLASTIC PROSTATE WITH BENIGN PROSTATIC HYPERPLASIA.

PART 5: SPERMATIC CORD, LIPOMA, RESECTION

FRAGMENTS OF LIPOMA, 6.5 CM.

COMMENT

{Not Entered}

GROSS DESCRIPTION

Part 1 is labeled with the patient's name, initials [REDACTED] and "right pelvic lymph nodes".

Specimen Received: Fresh

[page 3 of 5]
Type of Specimen Received: 11.0 x 8.5 x 2.0 cm in aggregate, portions of yellow lobulated fibroadipose tissue.

Dissection: Reveals 9 possible lymph nodes ranging from 0.3 x 0.2 x 0.2cm to 4.0 x 3.0 x 0.5 cm.

Representative sections are submitted SNAP frozen for possible further studies: no

Block Summary:

1A 6 possible lymph nodes

1B 2 possible lymph nodes

1C-1F 1 possible lymph node serially sectioned.

Formalin exposure time: 34 hours

Part 2 is labeled with the patient's name, initials [REDACTED] and "left pelvic lymph nodes".

Specimen Received: Fresh

Type of Specimen Received: 11.0 x 5.0 x 2.0 cm in aggregate, portions of yellow lobulated fibroadipose tissue.

Dissection: Reveals 8 possible lymph nodes ranging from 0.3 x 0.2 x 0.2 cm to 6.0 x 1.5 x 0.5 cm.

Representative sections are submitted SNAP frozen for possible further studies: no

Block Summary:

2A 6 possible lymph nodes

2B 1 possible lymph node bisected

2C-2F 1 possible lymph node serially sectioned

Formalin exposure time: 34 hours

Part 3 is labeled with the patient's name, initials [REDACTED] and "anterior fat pad".

Specimen Received: Fresh

Type of Specimen Received: Irregular aggregate of soft yellow adipose tissue. Dissection reveals yellow lobular adipose tissue. No lymph nodes are grossly identified.

Measurements: 5.0 x 2.5 x 1.0 cm overall.

Block Summary:

3A-3C -entire specimen

Formalin exposure time: 34 hours

Part 4 is labeled with the patient's name, initials [REDACTED] and "prostate".

Specimen Received: Fresh

Type of Specimen Received: Intact prostate with attached seminal vesicles and vasa deferentia.

Weight of Specimen: 84.0 g.

[page 4 of 5]
Size of Specimen:

Prostate:

Right to Left: 5.6 cm.

Superior to Inferior: 4.8 cm.

Anterior to Posterior: 4.5cm.

Seminal Vesicles:

Right: 4.4 x 1.8 x 0.8 cm.

Left: 3.6 x 1.5 x 1.2 cm.

Vas Deferens:

Right: 5.0 cm length, 0.5 cm diameter.

Left: 4.5 cm length, 0.5 cm diameter.

Orientation:

Right Side: black ink.

Left Side: orange ink.

Gross Description of Prostate:

Urethra: Probe patent: yes.

Capsule: Stripped: yes

Sutured vascular ligation on anterior surface 2.8 x 1.2 cm.

Number of Levels: 11 (distal to proximal).

Lesion Description:

Proximal Urethral Margin: Grossly unremarkable.

Distal Urethral Margin: Grossly unremarkable.

Capsule: There is a 4.5 x 1.4 cm firm yellow area in the entire right lateral aspect and a 4.7 x 3.5 cm area in the entire right side extending into the left posterior and left mid aspects.

Cut Surfaces: There is a 1.8 x 0.8 x 0.4 cm firm tan-yellow area in the left posterior aspect of levels 1-2. The remaining prostatic parenchyma is roughened with dimpling and multiple confluent nodules. There is a 1.2 x 0.6 x 0.4 cm dark hemorrhagic area in the left posterior aspect of levels 6-7.

Digital Photograph Taken: no.

Levels 3,5,7,9, and 11 are submitted SNAP frozen for possible further studies.

Block Summary:

The following sections are submitted:

4A - right seminal vesicle and vas deferens

4B - right vas deferens margin

4C - left seminal vesicle and vas deferens

4D - left vas deferens margin

4E-4H - proximal urethral margin, radially sectioned (4E = right anterior, 4F = right posterior, 4G = left anterior, 4H = left posterior)

4I-4L - distal urethral margin, radially sectioned (4I = right anterior, 4J = right posterior, 4K = left anterior, 4L = left posterior)

4M-4N - capsule, anterior right apex

4O-4P - capsule, anterior right mid

4Q-4R - capsule, anterior right base

4S-4U - capsule, anterior left apex

[page 5 of 5]
4V-4X - capsule, anterior left mid
4Y-4Z - capsule, anterior left base
4AA-4AB - capsule, posterior right apex
4AC-4AD - capsule, posterior right mid
4AE-4AF - capsule, posterior right base
4AG - capsule, posterior left apex
4AH - capsule, posterior left mid
4AI - capsule, posterior left base
4AJ - level 1, right
4AK - level 1, left
4AL - level 2, right
4AM - level 2, left
4AN - level 4, right anterior
4AO - level 4, right posterior
4AP - level 4, left anterior
4AQ - level 4, left posterior
4AR - level 6, right anterior
4AS - level 6, right posterior
4AT - level 6, left anterior
4AU - level 6, left posterior
4AV - level 8, right anterior
4AW - level 8, right posterior
4AX - level 8, left anterior
4AY-4AZ - level 8, left posterior
4BA-4BB - level 10, right
4BC - level 10, left

Formalin exposure time: 29 hours

Part 5 is labeled with the patient's name, initials [REDACTED] and "lipoma of cord".

Specimen Received: Fresh

Type of Specimen Received: 3 irregular fragments of encapsulated, glistening adipose.
The specimen is inked black and serially sectioned to reveal yellow homogenous adipose.

Measurements: 3.0 x 1.0 x 0.8 cm to 6.5 x 4.5 x 2.0 cm.

Digital Photograph Taken: no.

Tissue SNAP frozen for possible further studies: no.

Block Summary:

5A-5C representative sections

Formalin exposure time: 31 hours 30 minutes

Grossed by: [REDACTED]

MICROSCOPIC DESCRIPTION

The microscopic findings substantiate the diagnosis.

INTRAOPERATIVE DIAGNOSIS

{Not Entered}

Source: NCI Genomic Data Commons file 8ec4a7c4-a157-4fac-ac06-c4d11064e555 (TCGA-EJ-AB20.C1D97704-7C64-4C39-8812-BD8B95C2299F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).